Somatic mutation profile of tumor specimen TCGA-F2-A8YN-01A (aliquot TCGA-F2-A8YN-01A-11D-A377-08) from TCGA case TCGA-F2-A8YN, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 76.8 years (28,047 days).
Specimen TCGA-F2-A8YN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1a777c5-6a76-4b3f-b3df-68b04e09e3e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F2-A8YN-10A (Blood Derived Normal), aliquot TCGA-F2-A8YN-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38855715-405c-422a-b97d-766f57dd440d

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 5, Frame Shift Del 2, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 76/223 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659_669del p.Y220* | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADCY5 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs1412508852, COSV100567663; called by muse, mutect2, varscan2
- ALDH1L2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV51559789; called by muse, mutect2, varscan2
- C9 | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 40/634 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99662050; called by muse, mutect2
- CDKN2A | c.53_56delinsT p.T18_A19delinsI | In Frame Del (DEL) | VAF 28/109 reads (26%) | catalogued as COSV58713242; called by pindel, varscan2*
- CPAMD8 | c.2764G>A p.V922I (on ENST00000651564; = p.V875I on NM_015692.5) | Missense Mutation (SNP) | VAF 247/797 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.789); catalogued as rs199613595, COSV71595963; called by muse, mutect2, varscan2
- CYP2A7 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 126/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151290022; called by muse, mutect2, varscan2
- DKC1 | c.1045T>A p.L349I | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV101059878; called by muse, mutect2
- FUT9 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 94/268 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs371644802; called by muse, mutect2, varscan2
- HERC1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs766581151, COSV101496554; called by muse, mutect2, varscan2
- HOXA9 | c.744G>C p.R248S | Missense Mutation (SNP) | VAF 25/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604403; called by muse, mutect2
- HTR2C | c.998T>A p.L333Q | Missense Mutation (SNP) | VAF 156/443 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99349285; called by muse, mutect2, varscan2
- HYDIN | c.2015C>A p.A672E | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99863116; called by muse, mutect2, varscan2
- KCNJ12 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs144590967; called by muse, varscan2
- KCTD19 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 144/586 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753673167, COSV58574088; called by muse, mutect2, varscan2
- KRT26 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 256/625 reads (41%) | catalogued as COSV59414523; called by muse, mutect2, varscan2
- L3MBTL4 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs370465816; called by muse, mutect2
- LINS1 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 62/497 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs572636883, COSV100130219; called by muse, mutect2, varscan2
- MAP7D1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780680990, COSV100294453; called by muse, varscan2
- MYH13 | c.5378C>T p.T1793M | Missense Mutation (SNP) | VAF 223/566 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs773006118, COSV52823185; called by muse, mutect2, varscan2
- MYLK | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 208/783 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1302330903, COSV100659045; called by muse, mutect2, varscan2
- MYO18B | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs764599538, COSV100123593, COSV59143117; called by muse, mutect2, varscan2
- NALCN | c.3541C>T p.R1181* | Nonsense Mutation (SNP) | VAF 58/234 reads (25%) | catalogued as rs751434431, COSV51931682; called by muse, mutect2, varscan2
- OLIG3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 82/589 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100880267; called by muse, mutect2, varscan2
- OR10X1 | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 44/644 reads (7%) | catalogued as COSV100936659; called by muse, mutect2
- OR11H12 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 198/924 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101612489, COSV73569122; called by muse, mutect2, varscan2
- PRELID3B | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 234/744 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100582226; called by muse, mutect2, varscan2
- PTCH1 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100108507; called by muse, mutect2, varscan2
- RBBP6 | c.2159G>T p.S720I | Missense Mutation (SNP) | VAF 31/533 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100154588; called by muse, mutect2
- RMND5B | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs753302659, COSV99200933; called by muse, mutect2, varscan2
- ROBO1 | c.4070C>A p.S1357Y | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV101458696; called by muse, mutect2
- SST | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 192/1187 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.358); catalogued as COSV55030581; called by muse, mutect2, varscan2
- STX11 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100845488; called by muse, mutect2
- TAS2R8 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 13/257 reads (5%) | catalogued as COSV53687983; called by muse, mutect2
- THADA | c.3155G>A p.C1052Y | Missense Mutation (SNP) | VAF 238/894 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1009680633, COSV100368603; called by muse, mutect2, varscan2
- TMEM45B | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 153/535 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55653217, COSV99859366; called by muse, mutect2, varscan2
- TRPC4 | c.2659G>C p.E887Q (on ENST00000379705 / NM_016179.4; = p.E892Q on NM_003306.3) | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV100156792; called by muse, mutect2, varscan2
- UNC79 | c.626C>T p.S209F (on ENST00000393151 / NM_001346218.2; = p.S32F on NM_020818.5) | Missense Mutation (SNP) | VAF 21/453 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as rs953436830, COSV99827743; called by muse, mutect2
- USP37 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1189191334, COSV99294400; called by muse, mutect2, varscan2
- WDR33 | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 154/537 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as rs770070256, COSV59246071; called by muse, mutect2, varscan2
- ZNRF3 | c.1231C>T p.Q411* (on ENST00000544604 / NM_001206998.2; = p.Q311* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 58/213 reads (27%) | catalogued as COSV100238439; called by muse, mutect2, varscan2
- ITPR2 | c.1619_1620del p.D540Afs*36 | Frame Shift Del (DEL) | VAF 391/1226 reads (32%) | called by mutect2, pindel, varscan2
- ASH1L | c.5700T>C p.V1900= | Silent (SNP) | VAF 107/381 reads (28%) | catalogued as COSV100853408; called by muse, mutect2, varscan2
- ATP12A | c.30C>T p.S10= | Silent (SNP) | VAF 98/367 reads (27%) | catalogued as COSV99517600; called by muse, mutect2, varscan2
- CD164 | c.516G>A p.L172= | Silent (SNP) | VAF 147/263 reads (56%) | catalogued as COSV99248794; called by muse, mutect2, varscan2
- CPED1 | c.1371C>T p.F457= | Silent (SNP) | VAF 95/360 reads (26%) | catalogued as rs1412457081, COSV59997083; called by muse, mutect2, varscan2
- DNAI3 | c.1734C>T p.H578= | Silent (SNP) | VAF 156/588 reads (27%) | catalogued as rs754303337, COSV99641810; called by muse, mutect2, varscan2
- ONECUT1 | c.435G>A p.V145= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as COSV100009224; called by muse, mutect2, varscan2
- PCDHB6 | c.639G>A p.A213= | Silent (SNP) | VAF 88/299 reads (29%) | catalogued as rs1554277534, COSV99170112; called by muse, mutect2, varscan2
- PCDHGA10 | c.2301G>A p.S767= | Silent (SNP) | VAF 156/876 reads (18%) | catalogued as rs765634887, COSV99537888; called by muse, mutect2, varscan2
- ROBO1 | c.4071C>T p.S1357= | Silent (SNP) | VAF 9/224 reads (4%) | catalogued as COSV71399904; called by muse, mutect2
- SAMD14 | c.876C>A p.P292= (on ENST00000330175 / NM_001257359.2; = p.P320= on NM_174920.4) | Silent (SNP) | VAF 7/172 reads (4%) | catalogued as COSV99142948; called by muse, mutect2
- SUSD1 | c.699T>C p.H233= | Silent (SNP) | VAF 209/762 reads (27%) | catalogued as rs758198660, COSV100813154; called by muse, mutect2, varscan2
- SYT9 | c.1155A>G p.T385= | Silent (SNP) | VAF 73/402 reads (18%) | catalogued as COSV100608141; called by muse, mutect2, varscan2
- TAS1R2 | c.897C>T p.I299= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs753512335, COSV100946217; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048181 T>C | 5'Flank (SNP) | VAF 81/261 reads (31%) | catalogued as rs750076849; called by muse, mutect2, varscan2
- SLIT3 | c.1459+4622C>T | Intron (SNP) | VAF 6/143 reads (4%) | catalogued as rs1187325977, COSV100267375; called by muse, mutect2
